Somatic mutation profile of tumor specimen TCGA-09-0365-01A (aliquot TCGA-09-0365-01A-02W-0371-08) from TCGA case TCGA-09-0365, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 70.4 years (25,703 days).
Specimen TCGA-09-0365-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe0f59d7-35ce-4d52-aca3-c741f4c005f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-09-0365-10A (Blood Derived Normal), aliquot TCGA-09-0365-10A-01W-0371-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33961a9d-d3c5-4410-83f1-0448e7c7b85f

The open-access MAF lists 58 somatic variants for this specimen: 45 protein-altering or splice-affecting, 11 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 11, Nonsense Mutation 5, Frame Shift Ins 2, Splice Site 1, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 186/188 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs760043106, CM092575, COSV52661172, COSV52664264, COSV52684176, COSV52720899; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1739G>A p.R580Q | Missense Mutation (SNP) | VAF 88/201 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs749217850, COSV99771151; called by muse, mutect2, varscan2
- ADAR | c.289G>A p.V97M | Missense Mutation (SNP) | VAF 60/566 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.841); catalogued as rs750065985, COSV52715948; called by muse, mutect2, varscan2
- ADARB1 | c.1298G>T p.G433V | Missense Mutation (SNP) | VAF 17/124 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100653560; called by muse, mutect2, varscan2
- ADGRF5 | c.3526G>A p.A1176T | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as rs573068708, COSV51941787; called by muse, mutect2, varscan2
- ADNP | c.2942T>G p.V981G | Missense Mutation (SNP) | VAF 110/491 reads (22%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV100823618; called by muse, mutect2, varscan2
- AP3M1 | c.564C>G p.D188E | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100786616; called by muse, mutect2, varscan2
- ATP1A3 | c.1977C>A p.N659K (on ENST00000545399 / NM_001256214.2; = p.N646K on NM_152296.5) | Missense Mutation (SNP) | VAF 99/842 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as COSV100131802, COSV57488759; called by muse, mutect2, varscan2
- ATXN2 | c.3377C>T p.T1126M (on ENST00000550104; = p.T966M on NM_002973.4) | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.925); catalogued as rs1187452732, COSV66481327, COSV66485831; called by muse, mutect2, varscan2
- C20orf194 | c.3359G>A p.G1120D | Missense Mutation (SNP) | VAF 6/85 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1208790574, COSV99330055; called by muse, mutect2
- CDYL | c.1714G>T p.E572* (on ENST00000328908 / NM_001368125.1; = p.E518* on NM_004824.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 28/56 reads (50%) | catalogued as COSV59359522; called by muse, mutect2, varscan2
- CLCN1 | c.2960T>A p.I987N | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.077); catalogued as COSV100577586; called by muse, mutect2, varscan2
- DSG1 | c.2447C>T p.S816L | Missense Mutation (SNP) | VAF 126/512 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); catalogued as rs372724391, COSV99935466; called by muse, mutect2, varscan2
- FUBP3 | c.236C>T p.T79M | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs777125650, COSV60514731; called by muse, mutect2, varscan2
- GABBR2 | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 65/65 reads (100%) | catalogued as COSV99408884; called by muse, mutect2, varscan2
- GABPB2 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 125/545 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100927179; called by muse, mutect2, varscan2
- GALNT8 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 99/756 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.438); catalogued as rs375631897; called by muse, mutect2, varscan2
- GALNT8 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 76/635 reads (12%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs150516489; called by muse, mutect2, varscan2
- GTPBP10 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 71/362 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs139533783; called by muse, mutect2, varscan2
- H1-7 | c.271C>T p.R91C | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as rs1193414348, COSV100622155; called by muse, mutect2
- HGF | c.1734T>A p.D578E | Missense Mutation (SNP) | VAF 56/261 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV99735172; called by muse, mutect2, varscan2
- HRNR | c.2555C>G p.S852* | Nonsense Mutation (SNP) | VAF 21/107 reads (20%) | catalogued as COSV100912733, COSV64259033; called by muse, mutect2, varscan2
- KDR | c.683T>C p.L228P | Missense Mutation (SNP) | VAF 33/184 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99816451; called by muse, mutect2, varscan2
- LTBP4 | c.4088A>G p.H1363R (on ENST00000308370 / NM_001042544.1; = p.H1326R on NM_003573.2) | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99180303; called by muse, mutect2, varscan2
- LVRN | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.642); catalogued as COSV100773267; called by muse, mutect2, varscan2
- MREG | c.338A>C p.E113A | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as COSV99614731; called by muse, mutect2, varscan2
- MVP | c.1826C>T p.S609L | Missense Mutation (SNP) | VAF 58/300 reads (19%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs371042454; called by muse, varscan2
- OGDH | c.1193C>G p.T398S | Missense Mutation (SNP) | VAF 97/513 reads (19%) | SIFT tolerated (0.62); PolyPhen benign (0.009); catalogued as COSV99758172; called by muse, mutect2, varscan2
- OR4L1 | c.28A>G p.T10A | Missense Mutation (SNP) | VAF 68/378 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.006); catalogued as COSV59848870; called by muse, mutect2, varscan2
- PGAP4 | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs747277975, COSV66388456; called by muse, mutect2, varscan2
- PRDM15 | c.910G>T p.E304* | Nonsense Mutation (SNP) | VAF 49/259 reads (19%) | catalogued as COSV54153827, COSV99063593, COSV99519148; called by muse, mutect2, varscan2
- RBM46 | c.380G>A p.R127Q | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.682); catalogued as rs752720613, COSV55977134; called by muse, mutect2, varscan2
- RGS17 | c.44T>A p.V15E | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.018); catalogued as COSV99242359; called by muse, mutect2, varscan2
- RLF | c.2927G>A p.R976Q | Missense Mutation (SNP) | VAF 60/381 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.942); catalogued as rs376171628; called by muse, mutect2, varscan2
- RNF138 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.759); catalogued as rs759513121, COSV55235481; called by muse, mutect2, varscan2
- RPUSD4 | c.73A>G p.T25A | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.009); catalogued as COSV100028568; called by muse, mutect2, varscan2
- SLC24A5 | c.991A>G p.K331E | Missense Mutation (SNP) | VAF 58/206 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.129); catalogued as COSV99981084; called by muse, mutect2, varscan2
- SLIT2 | c.2442A>T p.R814S | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.586); catalogued as COSV56570074; called by muse, mutect2, varscan2
- TULP3 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 66/504 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101237457, COSV68118181; called by muse, mutect2, varscan2
- UBE2E1 | c.47C>A p.S16* | Nonsense Mutation (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100135029; called by muse, mutect2, varscan2
- ZNF48 | c.733dup p.E245Gfs*35 | Frame Shift Ins (INS) | VAF 6/34 reads (18%) | catalogued as rs1205149098; called by pindel, varscan2
- CRTC2 | c.1674+1dup p.X558_splice | Splice Site (INS) | VAF 17/161 reads (11%) | called by mutect2, pindel, varscan2
- DMRTA1 | c.1117A>T p.N373Y | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.023); called by mutect2, varscan2
- EFCAB1 | c.470dup p.M157Ifs*4 | Frame Shift Ins (INS) | VAF 9/81 reads (11%) | called by mutect2, pindel, varscan2
- EGFR | c.260G>A p.G87D | Missense Mutation (SNP) | VAF 246/1942 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- ADAMTSL1 | c.147C>T p.C49= | Silent (SNP) | VAF 17/30 reads (57%) | catalogued as rs895343655, COSV52807809; called by muse, mutect2, varscan2
- C16orf78 | c.78G>A p.R26= | Silent (SNP) | VAF 65/349 reads (19%) | catalogued as COSV54558932; called by muse, mutect2, varscan2
- CLCN1 | c.2961C>T p.I987= | Silent (SNP) | VAF 87/498 reads (17%) | catalogued as COSV100577587; called by muse, mutect2, varscan2
- CPA3 | c.429T>A p.I143= | Silent (SNP) | VAF 73/577 reads (13%) | catalogued as COSV99935892; called by muse, mutect2, varscan2
- PCDHA4 | c.1854G>A p.A618= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as rs185992398, COSV63541741; called by muse, mutect2, varscan2
- PSMA1 | c.594G>A p.T198= | Silent (SNP) | VAF 17/105 reads (16%) | catalogued as rs569675109, COSV67166090; called by muse, mutect2, varscan2
- RLF | c.1146C>G p.L382= | Silent (SNP) | VAF 63/299 reads (21%) | catalogued as COSV101034972; called by muse, mutect2, varscan2
- SCN2A | c.5889C>T p.T1963= | Silent (SNP) | VAF 98/282 reads (35%) | catalogued as rs776509462, COSV99329609; called by muse, mutect2, varscan2
- TRAPPC10 | c.1668C>G p.R556= | Silent (SNP) | VAF 24/118 reads (20%) | catalogued as COSV99378066; called by muse, mutect2, varscan2
- UTRN | c.8889C>T p.L2963= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV100837797; called by muse, mutect2, varscan2
- ZBTB21 | c.1374A>G p.S458= | Silent (SNP) | VAF 78/215 reads (36%) | catalogued as COSV100176820; called by muse, mutect2, varscan2
- GGNBP1 | chr6:33593075 C>T | 3'Flank (SNP) | VAF 3/12 reads (25%) | called by muse, mutect2
- NFASC | c.2470+2121G>A | Intron (SNP) | VAF 62/480 reads (13%) | catalogued as rs763954143, COSV100362463; called by muse, mutect2, varscan2
